TCGA case TCGA-BB-4217 — Head and Neck Squamous Cell Carcinoma (TCGA-HNSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Larynx; Tissue source site: Johns Hopkins. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/248fa778-0758-4681-a31f-371ea8d376e6

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 68 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C32.9; Tissue or organ of origin: Larynx, NOS; Site of resection or biopsy: Head, face or neck, NOS; Classification of tumor: primary; Age at diagnosis: 68.5 years (25,020 days); Year of diagnosis: 2008; AJCC staging edition: 7th; AJCC clinical T: T4a; AJCC clinical N: N2c; AJCC clinical M: M0; AJCC clinical stage: Stage IVA; AJCC pathologic T: T4a; AJCC pathologic N: N2c; AJCC pathologic M: M0; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 187 days.
   Pathology details: Lymph node dissection site: Neck, NOS.
   Pathology details: Consistent pathology review: Yes; Lymph nodes tested: 51; Margin status: Uninvolved.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Days to treatment start: 115 days; Days to treatment end: 121 days; Course number: 1.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: Cure; Days to treatment end: 52 days; Treatment outcome: Persistent Disease.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 187 days; Disease response: With Tumor.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 60.
- Alcohol history: Yes; Alcohol drinks per day: 10; Alcohol days per week: 7.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BB-4217-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.9; Intermediate dimension: 0.8; Shortest dimension: 0.3.
  Slide TCGA-BB-4217-01A-01-BS1: Section location: Bottom; Percent tumor cells: 24; Percent tumor nuclei: 30; Percent normal cells: 6; Percent necrosis: 21; Percent stromal cells: 49; Percent lymphocyte infiltration: 60.
  Slide TCGA-BB-4217-01A-01-TS1: Section location: Top; Percent tumor cells: 73; Percent tumor nuclei: 80; Percent normal cells: 6; Percent necrosis: 21; Percent stromal cells: 0; Percent lymphocyte infiltration: 10.
- Sample TCGA-BB-4217-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BB-4217-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Head and Neck; Histologic diagnosis: Head & Neck Squamous Cell Carcinoma; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Lymph nodes examined: Yes; Lymph node neck dissection indicator: Yes; Margin status: Negative; Tobacco smoking history indicator: 2; Alcohol consumption frequency: 7.
- Follow-up form 1: New tumor event diagnosis indicator: No; Tumor status: With tumor.
- Follow-up form 2: Lost to follow-up: Yes; Treatment outcome first course: Partial Remission/Response; Tumor status: With tumor; Treatment outcome at TCGA followup: Partial Remission/Response; Tobacco smokeless use at diagnosis: No; Tobacco smokeless regular use: No; Definitive treatment method: Surgery; Definitive treatment evidence disease after: Yes; New tumor event diagnosis indicator: No.
- Follow-up form 3: Lost to follow-up: Yes; Treatment outcome first course: Partial Remission/Response; Tumor status: With tumor; Treatment outcome at TCGA followup: Progressive Disease; Tobacco smokeless use at diagnosis: No; Tobacco smokeless regular use: No; Definitive treatment method: Surgery; Definitive treatment evidence disease after: Yes; Cause of death: Related to Head & Neck Cancer; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 187 days; disease-specific survival: no event (censored), 187 days; progression-free interval: no event (censored), 187 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BB-4217-01A-11D-2077-01): tumor purity 0.14, ploidy 2.16, whole-genome doublings 0.
